Surgical pathology report (de-identified scan), TCGA case TCGA-FY-A40K, project TCGA-THCA (Thyroid Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-FY-A40K-01A (Primary Tumor).

[page 1 of 3]
Referring Physician:

DOB: Age: Gender:

Ref#: Hosp#: Provider Group:

Date of Service: Date Received: Outpatient Case #:
Room: Bed: Date Reported:

FINAL SURGICAL PATHOLOGY REPORT

Diagnosis:

A. - C.) THYROID AND CENTRAL LYMPH NODES, THYROIDECTOMY (SUBMITTED SEPARATELY AS LEFT AND RIGHT THYROID LOBES) AND BIOPSY OF CENTRAL LYMPH NODES:

- MULTIFOCAL PAPILLARY THYROID CARCINOMA, CONFINED WITHIN THYROID.
- Largest tumor nodule measures 1 cm in diameter, present at inferior pole of right lobe.
- Smaller nodule present in mid portion of right lobe, measuring less than 0.1 cm in diameter.
- Reparative change in right thyroid lobe, secondary to previous fine needle aspiration.
- No evidence of neoplasm in left thyroid lobe.
- FOUR BENIGN LYMPH NODES, NO TUMOR PRESENT (0/4).

PATHOLOGIC TUMOR STAGING SYNOPSIS:

Type and grade: Multifocal papillary thyroid carcinoma.
Primary tumor: pT1a.
Regional lymph nodes: pN0.
Distant metastasis: Not applicable.
Stage: I.
Lymphovascular invasion: Not identified.
Margin status: Negative.

Case Is Archived		X

Intradepartmental consultation: Dr. [redacted] has reviewed representative slides, and concurs with the diagnosis of papillary thyroid carcinoma.

Tumor Staging Information

Data derived from current specimen. Staging in accordance with or modified from AJCC Cancer Staging Handbook, Ed, and CAP protocol,

ICD-O-3

carcinoma, papillary, thyroid

8260/3

Site: thyroid, NOS C73.9 7-3-12 RO

Page 1

Case #:

Printed:

This report continues... (FINAL)

Acct No. -

Patient Name -

Page 1

[page 2 of 3]
Case #:

Procedure:

Specimen type:

Specimen size:

TUMOR FEATURES:

Tumor size:

Tumor focality:

Laterality:

Histologic type:

Lymphovascular invasion:

Extrathyroidal extension:

LYMPH NODES:

MARGIN EVALUATION:

Distance to closest margin:

PATHOLOGIC TUMOR STAGING:

Primary tumor:

Regional lymph nodes:

Distant metastasis:

Margin status:

Pathologic stage:

Additional pathologic findings:

Thyroidectomy.

Left and right thyroid lobes separately submitted, with central node biopsies.

See gross description.

1 cm (largest nodule).

Multifocal.

Two tumor nodules present in right lobe of thyroid.

Papillary thyroid carcinoma.

Not identified.

Not identified.

Four benign lymph nodes (three lymph nodes in specimen C, one lymph node in specimen A).

Carcinoma is confined within thyroid gland, less than 0.1 cm from external aspect of thyroid (inferior pole).

pT1a.

pN0.

Not applicable.

Negative.

I.

Repair reaction secondary to previous FNA.

MD, Pathologist

Signed by

Case #:

Printed:

Phone:

Page 2

This report continues... (FINAL)

Acct No. -

Patient Name -

Page 2

[page 3 of 3]
Case #:

FINAL SURGICAL PATHOLOGY REPORT

Source of Specimen:

- A. Thyroid; Right lobe
- B. Thyroid; Left lobe
- C. Central nodule tissue

Clinical History/Operative Dx:

Thyroid mass

Intraoperative Diagnosis:

- A. Right thyroid lobe: Papillary thyroid carcinoma. (Dr.

Gross Description:

A. Received fresh is an 8 gram right thyroid lobe that measures 5.0 x 2.6 x 1.5 cm. In the inferior pole, there is a mass measuring 1.0 cm confined to the thyroid lobe. A representative portion is submitted in FSA1 for frozen section diagnosis. The remainder of the mass is submitted in A2. The remainder of the lobe is entirely submitted from superior to inferior in cassettes A3-A9.

B. Received in formalin labeled with the patient's name and "left thyroid lobe" is a 6 gram thyroid lobe that measures 4.5 x 2.4 x 1.5 cm. The cut surface is purple and soft with no distinct lesions. The lobe is entirely submitted from superior to inferior in cassettes B1-B6.

C. Received labeled with the patient's name and information and "central nodal tissue" is an irregular fragment of fibroadipose tissue measuring 2.0 x 2.0 x 0.3 cm. The specimen is entirely submitted without sectioning in cassette C1

Microscopic Description:

A. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

B. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

C. Microscopic sections have been examined. The microscopic findings are reflected in the diagnosis rendered.

Case #

Printed:

Phone:

Page 3

END OF REPORT (FINAL)

Patient Name

Source: NCI Genomic Data Commons file ed9d3f20-3245-4505-817e-44ff901a3647 (TCGA-FY-A40K.EEF7A2AF-C12B-49F5-91CE-458B62D3F4D7.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).